Gene-level copy-number profile of tumor specimen MP2PRT-PAUPSD-TMP1-A from MP2PRT case MP2PRT-PAUPSD, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.1 years (1,513 days).
Specimen MP2PRT-PAUPSD-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3a38e2f6-7f04-49e0-b089-d6c57cf48b21.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAUPSD-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,224 have no estimate.
https://portal.gdc.cancer.gov/files/eb59ab21-79a1-4e83-9a23-df045b7d5f32

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 102; copy number 1: 268; copy number 2: 58,021; copy number 3: 8.

Homozygous deletions (total copy number 0; autosomes only): 102 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,857,161–89,254,015, 40 genes (within-gene range 0–2): IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29, IGKV2-30, IGKV3-31, IGKV1-32.
- chr2:90,046,796–90,221,384, 14 genes: IGKV2D-19, IGKV2D-18, IGKV6D-41, IGKV1D-17, IGKV1D-16, IGKV3D-15, IGKV2D-14, IGKV1D-13, IGKV1D-12, IGKV3D-11, IGKV2D-10, IGKV1D-42, IGKV1D-43, IGKV1D-8.
- chr6:26,124,145–26,246,996, 22 genes (within-gene range 0–2): H2AC6, H1-4, H2BC5, AL353759.1, LARP1P1, H2BC6, H4C4, H1-12P, AL031777.2, H3C4, H2AC7, H2BC7, AL031777.1, H4C5, H2BC8, H2AC8, H3C5P, H3C6, H2AC9P, H1-3, H4C6, H4C7.
- chr14:106,373,663–106,411,021, 6 genes (within-gene range 0–1): IGHV4-34, IGHV7-34-1, IGHV3-35, IGHV3-36, IGHV3-37, IGHV3-38.
- chr14:106,421,711–106,422,218, 1 gene (within-gene range 0–1): IGHV4-39.
- chr14:106,436,415–106,461,055, 4 genes (within-gene range 0–1): AC244452.1, IGHVII-40-1, IGHV3-41, HOMER2P1.
- chr14:106,470,264–106,470,800, 1 gene (within-gene range 0–1): IGHV3-43.
- chr14:106,482,435–106,538,344, 9 genes (within-gene range 0–1): LINC00221, IGHVIV-44-1, IGHVII-44-2, IGHV1-45, IGHV1-46, IGHVII-46-1, IGHV3-47, IGHVIII-47-1, IGHV3-48.
- chr14:106,564,375–106,579,236, 3 genes (within-gene range 0–1): IGHVII-49-1, IGHV3-50, IGHV5-51.
- chr14:106,584,718–106,586,826, 2 genes (within-gene range 0–1): IGHVII-51-2, IGHV3-52.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 268. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
